Somatic mutation profile of tumor specimen C3N-02919-02 (aliquot CPT0216100007) from CPTAC case C3N-02919, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 57.9 years (21,151 days).
Specimen C3N-02919-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 979f9153-6c6e-4101-a602-9b551faf4aa6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02919-71 (Blood Derived Normal), aliquot CPT0216210002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b72fd88e-0f89-4172-84e6-0a36f2c26e0b

The open-access MAF lists 386 somatic variants for this specimen: 252 protein-altering or splice-affecting, 85 silent, 49 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 226, Silent 85, Intron 21, Nonsense Mutation 14, 5'Flank 10, RNA 8, Splice Site 6, 3'UTR 5, 5'UTR 5, Frame Shift Del 4, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC47 | c.811C>T p.R271* | Nonsense Mutation (SNP) | VAF 13/170 reads (8%) | catalogued as rs749027804, COSV56724268; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- TP53 | c.503A>G p.H168R | Missense Mutation (SNP) | VAF 68/291 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs867114783, COSV52676197, COSV52682212, COSV52698349, COSV52762255; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ADAMTS14 | c.2794G>T p.G932W | Missense Mutation (SNP) | VAF 16/179 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.014); catalogued as COSV64607266; called by muse, mutect2
- ANKIB1 | c.2507G>A p.R836H | Missense Mutation (SNP) | VAF 18/307 reads (6%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); catalogued as rs569611694; called by muse, mutect2
- APOBEC3F | c.527A>G p.N176S | Missense Mutation (SNP) | VAF 67/257 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.848); catalogued as rs772506680; called by muse, mutect2, varscan2
- ARMC4 | c.2315T>C p.V772A | Missense Mutation (SNP) | VAF 33/361 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59467343; called by muse, mutect2
- ARRDC5 | c.775G>T p.V259L (on ENST00000381781; = p.V245L on NM_001080523.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/211 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV67787735; called by muse, mutect2, varscan2
- ATP9B | c.169A>T p.M57L | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.005); catalogued as rs774554333; called by mutect2, varscan2
- BAZ1A | c.1231C>T p.P411S | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62411750; called by muse, mutect2, varscan2
- C12orf40 | c.206C>T p.T69I | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.105); catalogued as COSV61138695; called by muse, mutect2
- CATSPER1 | c.2270G>A p.R757H | Missense Mutation (SNP) | VAF 72/462 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs748502205, COSV100376270; called by muse, mutect2, varscan2
- CD6 | c.730C>T p.P244S | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.953); catalogued as rs1444651842; called by muse, mutect2, varscan2
- CNGB3 | c.403C>G p.L135V | Missense Mutation (SNP) | VAF 39/581 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.801); catalogued as rs767209573, COSV60692437; called by muse, mutect2
- CNTN6 | c.1649A>G p.H550R | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs759309603; called by muse, mutect2
- COP1 | c.2155G>A p.A719T | Missense Mutation (SNP) | VAF 47/193 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV58167602; called by muse, mutect2, varscan2
- CYP21A2 | c.715G>T p.E239* | Nonsense Mutation (SNP) | VAF 233/819 reads (28%) | catalogued as COSV100926763, COSV64474914; called by muse, mutect2, varscan2
- DAW1 | c.485G>T p.W162L | Missense Mutation (SNP) | VAF 44/214 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV100005855; called by muse, mutect2, varscan2
- DBH | c.17G>A p.R6H | Missense Mutation (SNP) | VAF 48/190 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs781667738; called by muse, mutect2, varscan2
- DNAJC18 | c.560G>A p.G187E | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs141875926; called by muse, mutect2, varscan2
- DPPA3 | c.313G>T p.G105C | Missense Mutation (SNP) | VAF 23/265 reads (9%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.578); catalogued as COSV100559832; called by muse, mutect2
- DSC3 | c.520A>G p.S174G | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.098); catalogued as rs1199819451; called by muse, mutect2
- DSG1 | c.1693C>T p.P565S | Missense Mutation (SNP) | VAF 120/462 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV99935897; called by muse, mutect2, varscan2
- ELMO1 | c.1300+1G>A p.X434_splice | Splice Site (SNP) | VAF 14/139 reads (10%) | catalogued as rs1486694290, COSV60295508; called by muse, mutect2, varscan2
- ERBB2 | c.874G>C p.G292R | Missense Mutation (SNP) | VAF 80/274 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54063997, COSV99507040; called by muse, mutect2, varscan2
- FAM83G | c.262C>G p.Q88E | Missense Mutation (SNP) | VAF 9/177 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs969896084, COSV58756629, COSV58759158; called by muse, mutect2
- FAT1 | c.4115C>G p.P1372R | Missense Mutation (SNP) | VAF 21/306 reads (7%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.988); catalogued as COSV101499085; called by muse, mutect2
- FOXP2 | c.1709G>A p.G570E | Missense Mutation (SNP) | VAF 31/278 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63482328; called by muse, mutect2, varscan2
- G3BP2 | c.515A>G p.N172S | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1438364937; called by muse, mutect2, varscan2
- GOLPH3 | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 43/171 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1408121699; called by muse, mutect2, varscan2
- GRID2 | c.110C>G p.A37G | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.978); catalogued as COSV99938444; called by muse, mutect2, varscan2
- GRID2IP | c.185G>T p.R62L | Missense Mutation (SNP) | VAF 56/316 reads (18%) | SIFT tolerated (0.65); PolyPhen benign (0.158); catalogued as rs752672201, COSV71850010; called by muse, varscan2
- GRIK4 | c.2482T>A p.L828I | Missense Mutation (SNP) | VAF 39/270 reads (14%) | SIFT tolerated (0.97); PolyPhen benign (0.014); catalogued as COSV70801417; called by muse, mutect2, varscan2
- GRIK5 | c.1852C>T p.R618C | Missense Mutation (SNP) | VAF 43/219 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs750145451, COSV53476974, COSV53484373; called by muse, mutect2, varscan2
- GSDMC | c.502A>T p.T168S | Missense Mutation (SNP) | VAF 41/156 reads (26%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.502); catalogued as COSV52698345; called by muse, mutect2, varscan2
- H1-2 | c.549G>C p.K183N | Missense Mutation (SNP) | VAF 13/392 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59189495, COSV59192261; called by muse, mutect2
- HOXB3 | c.1252C>T p.P418S | Missense Mutation (SNP) | VAF 28/495 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV57486001; called by muse, mutect2
- IER3IP1 | c.28C>T p.Q10* | Nonsense Mutation (SNP) | VAF 53/509 reads (10%) | catalogued as rs1216275478; called by muse, mutect2, varscan2
- IL3RA | c.932C>T p.A311V | Missense Mutation (SNP) | VAF 63/351 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.125); catalogued as rs1372137893; called by muse, mutect2, varscan2
- INSRR | c.258C>A p.F86L | Missense Mutation (SNP) | VAF 120/326 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100948247; called by muse, mutect2, varscan2
- JADE1 | c.891G>T p.M297I | Missense Mutation (SNP) | VAF 30/189 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56910040; called by muse, mutect2, varscan2
- KCNB1 | c.2057C>A p.P686H | Missense Mutation (SNP) | VAF 56/201 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); catalogued as COSV65566561; called by muse, mutect2, varscan2
- KIAA0825 | c.1150G>A p.D384N | Missense Mutation (SNP) | VAF 13/135 reads (10%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs930705078; called by muse, mutect2
- KIF21B | c.4498G>A p.E1500K (on ENST00000422435 / NM_001252100.2; = p.E1487K on NM_017596.4) | Missense Mutation (SNP) | VAF 26/274 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.094); catalogued as rs778450016, COSV100144010; called by muse, mutect2
- KRTAP4-8 | c.365C>A p.P122H | Missense Mutation (SNP) | VAF 188/618 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.157); catalogued as COSV104414753; called by muse, mutect2, varscan2
- LIX1L | c.392C>G p.S131C | Missense Mutation (SNP) | VAF 15/311 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as rs587772132; called by muse, mutect2
- MAGEL2 | c.3008C>A p.S1003Y | Missense Mutation (SNP) | VAF 32/346 reads (9%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.038); catalogued as rs781747956, COSV58567711, COSV58569677; called by muse, mutect2
- MATN4 | c.21G>T p.W7C | Missense Mutation (SNP) | VAF 58/341 reads (17%) | PolyPhen benign (0); catalogued as COSV59213210; called by muse, mutect2, varscan2
- MMP19 | c.1001C>A p.P334H | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV59452539; called by muse, mutect2, varscan2
- MN1 | c.3124G>T p.G1042C | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV56561840; called by muse, mutect2, varscan2
- MNDA | c.476del p.P159Qfs*54 | Frame Shift Del (DEL) | VAF 23/116 reads (20%) | catalogued as COSV63741199; called by mutect2, pindel, varscan2
- MPEG1 | c.1330T>A p.F444I | Missense Mutation (SNP) | VAF 27/190 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.731); catalogued as COSV57090650; called by muse, mutect2, varscan2
- MUC12 | c.1972T>A p.S658T (on ENST00000379442; = p.S515T on NM_001164462.1) | Missense Mutation (SNP) | VAF 54/890 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.159); catalogued as rs1286918430; called by muse, mutect2
- MUC4 | c.13040G>A p.G4347D (on ENST00000463781 / NM_018406.7; = p.G111D on NM_004532.6) | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57796612; called by muse, mutect2
- MUC4 | c.6884C>T p.S2295F | Missense Mutation (SNP) | VAF 22/540 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.496); catalogued as rs1307398233, COSV100638977; called by muse, mutect2
- MUL1 | c.632A>C p.Q211P | Missense Mutation (SNP) | VAF 32/153 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1255379620; called by muse, mutect2, varscan2
- NF1 | c.5672A>T p.Q1891L (on ENST00000358273 / NM_001042492.3; = p.Q1870L on NM_000267.3) | Missense Mutation (SNP) | VAF 17/303 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.176); catalogued as COSV100647845; called by muse, mutect2
- NOTCH2 | c.5003-1G>A p.X1668_splice | Splice Site (SNP) | VAF 56/609 reads (9%) | catalogued as rs1178925130, COSV56705462; called by muse, mutect2
- NPY1R | c.588C>A p.Y196* | Nonsense Mutation (SNP) | VAF 21/132 reads (16%) | catalogued as COSV56715239; called by muse, mutect2, varscan2
- NSUN6 | c.340G>T p.A114S | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV101045487, COSV66031824; called by muse, mutect2
- NTSR1 | c.424C>A p.R142S | Missense Mutation (SNP) | VAF 97/472 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as rs112613610, COSV100980624; called by muse, mutect2, varscan2
- OR51V1 | c.266G>T p.W89L | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.075); catalogued as COSV58315550; called by muse, mutect2, varscan2
- OR52A1 | c.26A>T p.Y9F | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61092167, COSV61093420; called by muse, varscan2
- OR5L2 | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 26/170 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.248); catalogued as COSV65724532, COSV65724588; called by muse, mutect2, varscan2
- OR5W2 | c.378C>G p.I126M | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV60616146; called by muse, mutect2, varscan2
- OSBP | c.458A>G p.N153S | Missense Mutation (SNP) | VAF 78/533 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.402); catalogued as COSV55666037; called by muse, mutect2, varscan2
- OTOF | c.2605G>T p.D869Y (on ENST00000272371 / NM_194248.3; = p.D122Y on NM_004802.4) | Missense Mutation (SNP) | VAF 87/428 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as rs886055877, COSV55513000; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OTOGL | c.6436G>T p.E2146* (on ENST00000547103; = p.E2137* on NM_173591.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 6/55 reads (11%) | catalogued as rs1326817930, COSV54016378; called by muse, mutect2
- OTOP1 | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as rs952979671; called by muse, mutect2, varscan2
- PDK1 | c.964G>C p.G322R | Missense Mutation (SNP) | VAF 43/174 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1195090888; called by muse, mutect2, varscan2
- PIGT | c.953A>G p.Y318C | Missense Mutation (SNP) | VAF 79/347 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs763271618; called by muse, mutect2, varscan2
- PREX1 | c.1194G>T p.K398N | Missense Mutation (SNP) | VAF 18/208 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.48); catalogued as COSV64250706; called by muse, mutect2
- PYGM | c.1820G>T p.G607V | Missense Mutation (SNP) | VAF 42/456 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1194416311; called by muse, mutect2
- PZP | c.1285C>T p.H429Y | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs1175827993, COSV99737252; called by muse, mutect2
- QSER1 | c.3478G>T p.G1160W (on ENST00000399302; = p.G1289W on NM_001076786.3) | Missense Mutation (SNP) | VAF 17/209 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104434238; called by muse, mutect2
- RASGRF2 | c.1738A>T p.M580L | Missense Mutation (SNP) | VAF 31/172 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs926988606; called by muse, mutect2, varscan2
- RFPL4B | c.372C>A p.H124Q | Missense Mutation (SNP) | VAF 87/331 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.066); catalogued as COSV71437216; called by muse, mutect2, varscan2
- RREB1 | c.1658C>T p.S553L | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as rs766901239; called by muse, mutect2, varscan2
- SATB1 | c.1925G>A p.R642Q | Missense Mutation (SNP) | VAF 29/189 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.187); catalogued as rs1182895238, COSV58671854; called by muse, varscan2
- SI | c.4424C>A p.T1475N | Missense Mutation (SNP) | VAF 45/275 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV52292661; called by muse, mutect2, varscan2
- SMARCA4 | c.2534del p.V845Afs*13 | Frame Shift Del (DEL) | VAF 72/332 reads (22%) | catalogued as rs1285069421; called by mutect2, pindel, varscan2
- SNCAIP | c.29A>G p.D10G | Missense Mutation (SNP) | VAF 20/274 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1450884642; called by muse, mutect2
- SUGP1 | c.17A>G p.D6G | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.984); catalogued as rs1312547838; called by muse, mutect2, varscan2
- SYN3 | c.176T>A p.L59H | Missense Mutation (SNP) | VAF 22/311 reads (7%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.72); catalogued as COSV60509769; called by muse, mutect2
- TAS2R7 | c.632A>G p.H211R | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767521272; called by muse, mutect2
- TENM1 | c.7114C>T p.H2372Y | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.972); catalogued as COSV64433186; called by muse, mutect2, varscan2
- TENM4 | c.5558A>G p.Y1853C | Missense Mutation (SNP) | VAF 41/239 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1279332630; called by muse, mutect2, varscan2
- TIGD2 | c.14G>T p.R5L | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57648613; called by muse, varscan2
- TOGARAM2 | c.16G>T p.D6Y | Missense Mutation (SNP) | VAF 44/212 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); catalogued as COSV65423503; called by muse, mutect2, varscan2
- TRIM46 | c.2101C>T p.R701W | Missense Mutation (SNP) | VAF 20/673 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1279255486; called by muse, mutect2
- TSPOAP1 | c.2465G>A p.G822D | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.544); catalogued as COSV52106425; called by muse, mutect2
- TTI2 | c.1415G>A p.R472Q | Missense Mutation (SNP) | VAF 42/205 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs755926912, COSV100659745; called by muse, mutect2, varscan2
- TTN | c.60158A>G p.Y20053C (on ENST00000591111; = p.Y12629C on NM_003319.4) | Missense Mutation (SNP) | VAF 10/182 reads (5%) | PolyPhen probably damaging (0.98); catalogued as COSV100597449; called by muse, mutect2
- UNCX | c.649C>A p.R217S | Missense Mutation (SNP) | VAF 73/384 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs868147826, COSV60333268; called by muse, mutect2, varscan2
- ABCA4 | c.3986C>A p.P1329Q | Missense Mutation (SNP) | VAF 25/259 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.007); called by muse, mutect2
- ABCA4 | c.2177A>G p.H726R | Missense Mutation (SNP) | VAF 88/468 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- ABCC11 | c.3650A>G p.K1217R | Missense Mutation (SNP) | VAF 9/169 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.029); called by muse, mutect2
- ABHD13 | c.524A>T p.Y175F | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- AC126283.2 | c.152G>T p.W51L | Missense Mutation (SNP) | VAF 25/142 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACSM4 | c.1615C>A p.H539N | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ADAMTS14 | c.2795G>T p.G932V | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT tolerated (0.66); PolyPhen benign (0.006); called by muse, mutect2
- ADGRB1 | c.655G>T p.E219* | Nonsense Mutation (SNP) | VAF 24/216 reads (11%) | called by muse, mutect2, varscan2
- ADGRB3 | c.3842T>G p.V1281G | Missense Mutation (SNP) | VAF 64/217 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- ADGRG4 | c.3052C>G p.P1018A | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- AKAP8 | c.706G>A p.G236R | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ALPK1 | c.1860G>T p.Q620H | Missense Mutation (SNP) | VAF 13/215 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); called by muse, mutect2
- ANKRD30A | c.2862del p.K954Nfs*2 (on ENST00000611781; = p.K898Nfs*2 on NM_052997.2) | Frame Shift Del (DEL) | VAF 16/131 reads (12%) | called by mutect2, pindel, varscan2
- APC | c.7915G>T p.E2639* | Nonsense Mutation (SNP) | VAF 25/122 reads (20%) | called by muse, mutect2, varscan2
- BCAN | c.2108T>C p.F703S | Missense Mutation (SNP) | VAF 52/183 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- C1QTNF4 | c.196G>T p.G66C | Missense Mutation (SNP) | VAF 77/376 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C4orf54 | c.3035C>A p.P1012H | Missense Mutation (SNP) | VAF 28/262 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- C7orf31 | c.951G>T p.P317= | Splice Region (SNP) | VAF 10/83 reads (12%) | called by muse, mutect2, varscan2
- CACNA1H | c.1520C>T p.A507V | Missense Mutation (SNP) | VAF 46/156 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- CACNA2D3 | c.1346A>C p.D449A | Missense Mutation (SNP) | VAF 12/286 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); called by muse, mutect2
- CADPS | c.1654T>C p.Y552H | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- CALN1 | c.26G>T p.G9V (on ENST00000329008 / NM_001017440.3; = p.G51V on NM_031468.4) | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.494); called by muse, mutect2, varscan2
- CASP4 | c.502G>T p.G168C | Missense Mutation (SNP) | VAF 32/136 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- CBLB | c.2242G>T p.G748C | Missense Mutation (SNP) | VAF 27/225 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- CCDC22 | c.1756G>A p.D586N | Missense Mutation (SNP) | VAF 68/218 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCDC85A | c.1091A>T p.Q364L | Missense Mutation (SNP) | VAF 24/227 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- CDC14A | c.1170A>T p.K390N | Missense Mutation (SNP) | VAF 29/161 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- CDC42BPB | c.4148G>A p.R1383K | Missense Mutation (SNP) | VAF 37/154 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDK5R2 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 33/159 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- CEP152 | c.4035G>T p.M1345I (on ENST00000380950 / NM_001194998.2; = p.M1289I on NM_014985.4) | Missense Mutation (SNP) | VAF 35/372 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.202); called by muse, mutect2
- CFAP94 | c.808T>A p.S270T (on ENST00000320267 / NM_001352064.2; = p.S276T on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/316 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- CHAT | c.1591C>A p.P531T | Missense Mutation (SNP) | VAF 28/340 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- CHAT | c.1592C>G p.P531R | Missense Mutation (SNP) | VAF 26/342 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CHRNA9 | c.67G>T p.A23S | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2
- CMAS | c.955A>T p.I319F | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- COG5 | c.1545C>G p.I515M | Missense Mutation (SNP) | VAF 13/300 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.425); called by muse, mutect2
- CRYBG3 | c.1513G>A p.E505K | Missense Mutation (SNP) | VAF 22/169 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- CSTF2T | c.653G>A p.G218D | Missense Mutation (SNP) | VAF 32/323 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- CTR9 | c.3166G>T p.E1056* | Nonsense Mutation (SNP) | VAF 30/183 reads (16%) | called by muse, mutect2, varscan2
- CUBN | c.2206T>G p.Y736D | Missense Mutation (SNP) | VAF 64/302 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CUBN | c.943G>T p.G315C | Missense Mutation (SNP) | VAF 47/475 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CYP7B1 | c.361A>T p.K121* | Nonsense Mutation (SNP) | VAF 23/156 reads (15%) | called by muse, mutect2, varscan2
- DDIAS | c.1069C>A p.H357N | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- DGCR2 | c.146G>T p.W49L | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- DNAH11 | c.11125G>T p.A3709S | Missense Mutation (SNP) | VAF 40/367 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- DNAH17 | c.7813A>T p.N2605Y | Missense Mutation (SNP) | VAF 91/242 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.586); called by muse, mutect2, varscan2
- DNAH5 | c.12578C>G p.S4193C | Missense Mutation (SNP) | VAF 95/511 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- DOCK6 | c.317A>C p.D106A | Missense Mutation (SNP) | VAF 51/255 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DRD5 | c.59A>T p.Q20L | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- DUSP26 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 70/379 reads (18%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- EDA2R | c.852C>G p.D284E | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- ELAVL4 | c.112G>A p.G38R | Missense Mutation (SNP) | VAF 24/476 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.365); called by muse, mutect2
- ERBB4 | c.3251C>T p.P1084L | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2
- ERC2 | c.2128A>T p.K710* | Nonsense Mutation (SNP) | VAF 45/227 reads (20%) | called by muse, mutect2, varscan2
- FAHD2A | c.844G>T p.G282C | Missense Mutation (SNP) | VAF 28/324 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FAM160B1 | c.1799G>A p.R600K | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- FANCB | c.2070A>T p.E690D | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- FAP | c.182G>T p.W61L | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAT1 | c.9944T>G p.L3315R | Missense Mutation (SNP) | VAF 15/218 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- FAT1 | c.134A>C p.E45A | Missense Mutation (SNP) | VAF 28/270 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FAT4 | c.374T>A p.V125E | Missense Mutation (SNP) | VAF 13/245 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- FERMT3 | c.1625_1630del p.R542_I544delinsL (on ENST00000279227 / NM_178443.3; = p.R538_I540delinsL on NM_031471.6 and 3 other RefSeq transcripts) | In Frame Del (DEL) | VAF 22/262 reads (8%) | called by mutect2, pindel
- FLNB | c.4208G>A p.G1403E | Missense Mutation (SNP) | VAF 22/312 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.794); called by muse, mutect2
- FLT1 | c.1054T>C p.S352P | Missense Mutation (SNP) | VAF 61/439 reads (14%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- GABRR2 | c.714G>C p.R238S | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- GIMAP1-GIMAP5 | c.445A>G p.N149D | Missense Mutation (SNP) | VAF 38/391 reads (10%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- GIMAP2 | c.611A>T p.D204V | Missense Mutation (SNP) | VAF 35/220 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- GOSR1 | c.518C>T p.S173L | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- GRIN2B | c.2360-1G>T p.X787_splice | Splice Site (SNP) | VAF 44/303 reads (15%) | called by muse, mutect2, varscan2
- HDC | c.1886C>A p.A629D | Missense Mutation (SNP) | VAF 89/501 reads (18%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HLA-DRB1 | c.737T>A p.L246Q | Missense Mutation (SNP) | VAF 66/690 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- HOXC13 | c.389A>G p.Y130C | Missense Mutation (SNP) | VAF 51/184 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGFBP3 | c.286C>A p.P96T | Missense Mutation (SNP) | VAF 37/201 reads (18%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- IGKV3D-11 | c.186G>T p.Q62H | Missense Mutation (SNP) | VAF 91/871 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- INAVA | c.1598G>T p.G533V | Missense Mutation (SNP) | VAF 14/232 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.169); called by muse, mutect2
- KCNQ2 | c.1603G>C p.G535R (on ENST00000359125 / NM_172107.4; = p.G507R on NM_004518.6) | Missense Mutation (SNP) | VAF 82/372 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- KIF4B | c.2522T>A p.L841Q | Missense Mutation (SNP) | VAF 42/241 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- KIR2DL4 | c.1027G>T p.D343Y (on ENST00000396284; = p.D269Y on NM_001080770.2) | Missense Mutation (SNP) | VAF 149/694 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- LEMD3 | c.2042A>T p.N681I | Missense Mutation (SNP) | VAF 66/307 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- LRP1 | c.6562G>T p.A2188S | Missense Mutation (SNP) | VAF 64/252 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LSM11 | c.1004A>T p.Y335F | Missense Mutation (SNP) | VAF 48/224 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- MAP7 | c.1075G>C p.A359P | Missense Mutation (SNP) | VAF 12/236 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.694); called by muse, mutect2
- MITD1 | c.593+2T>G p.X198_splice | Splice Site (SNP) | VAF 13/91 reads (14%) | called by muse, mutect2
- MORC1 | c.1997T>C p.L666P | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.005); called by muse, mutect2
- MROH5 | c.753G>C p.M251I | Missense Mutation (SNP) | VAF 32/152 reads (21%) | SIFT tolerated (0.7); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MUC7 | c.880C>G p.P294A | Missense Mutation (SNP) | VAF 64/375 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- MYCN | c.487G>T p.G163C | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MYCN | c.488G>T p.G163V | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- MYH7 | c.3014A>G p.Q1005R | Missense Mutation (SNP) | VAF 56/528 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MYO10 | c.3274G>T p.D1092Y | Missense Mutation (SNP) | VAF 37/197 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- MYO18B | c.5371C>A p.H1791N | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.598); called by muse, mutect2
- NEFL | c.1304C>T p.S435F | Missense Mutation (SNP) | VAF 26/451 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.459); called by muse, mutect2
- NKG7 | c.143G>T p.G48V | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- NKG7 | c.142G>T p.G48W | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- NMD3 | c.586G>T p.D196Y | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NOP56 | c.93G>T p.Q31H | Missense Mutation (SNP) | VAF 71/209 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- NOS1 | c.1223A>G p.Y408C | Missense Mutation (SNP) | VAF 50/357 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- NPAP1 | c.2277_2278del p.S760Qfs*18 | Frame Shift Del (DEL) | VAF 58/296 reads (20%) | called by mutect2, pindel, varscan2
- NSMAF | c.658C>A p.L220M | Missense Mutation (SNP) | VAF 14/236 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- NWD2 | c.4443C>G p.I1481M | Missense Mutation (SNP) | VAF 26/264 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- OR10S1 | c.394A>T p.M132L | Missense Mutation (SNP) | VAF 37/262 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- OR11H2 | c.822G>T p.M274I (on ENST00000556246; = p.M285I on NM_001197287.1) | Missense Mutation (SNP) | VAF 56/820 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.013); called by muse, mutect2
- OR2T4 | c.616A>T p.I206F | Missense Mutation (SNP) | VAF 22/450 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- OR51A2 | c.105C>A p.S35R | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.19); called by muse, mutect2
- OTOG | c.6022C>T p.P2008S | Missense Mutation (SNP) | VAF 57/343 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PARP15 | c.1847A>T p.Y616F (on ENST00000464300 / NM_001113523.3; = p.Y382F on NM_152615.2) | Missense Mutation (SNP) | VAF 16/265 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); called by muse, mutect2
- PARVB | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 45/279 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- PDK3 | c.232G>T p.G78* | Nonsense Mutation (SNP) | VAF 29/121 reads (24%) | called by muse, mutect2, varscan2
- PDZRN4 | c.1450G>T p.A484S (on ENST00000402685 / NM_001164595.2; = p.A226S on NM_013377.4) | Missense Mutation (SNP) | VAF 50/263 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- PIGT | c.1119C>G p.Y373* | Nonsense Mutation (SNP) | VAF 45/302 reads (15%) | called by muse, mutect2, varscan2
- PIKFYVE | c.2082G>T p.K694N | Missense Mutation (SNP) | VAF 12/192 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2
- PIP4P1 | c.547-2A>T p.X183_splice | Splice Site (SNP) | VAF 44/280 reads (16%) | called by muse, mutect2, varscan2
- PIWIL3 | c.1705A>C p.M569L | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- PKD1L1 | c.3943A>G p.S1315G | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- PKD2 | c.2054C>G p.S685C | Missense Mutation (SNP) | VAF 29/189 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PPP4R3A | c.409T>A p.L137I | Missense Mutation (SNP) | VAF 100/323 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- RANBP17 | c.575C>T p.A192V | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- RASL10B | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 45/187 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- RBCK1 | c.323C>T p.A108V (on ENST00000356286 / NM_031229.4; = p.A66V on NM_006462.6) | Missense Mutation (SNP) | VAF 32/314 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.062); called by muse, mutect2
- RC3H2 | c.2393C>G p.P798R | Missense Mutation (SNP) | VAF 36/182 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- RDH10 | c.430A>T p.N144Y | Missense Mutation (SNP) | VAF 111/545 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RIPK4 | c.1432G>A p.D478N (on ENST00000352483; = p.D430N on NM_020639.3) | Missense Mutation (SNP) | VAF 15/205 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.159); called by muse, mutect2
- RNF220 | c.1261G>T p.E421* | Nonsense Mutation (SNP) | VAF 18/213 reads (8%) | called by muse, mutect2
- RUNX1T1 | c.1280-1G>T p.X427_splice (on ENST00000265814 / NM_001198628.1; = p.X400_splice on NM_004349.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 26/174 reads (15%) | called by muse, mutect2, varscan2
- RYR3 | c.7418G>T p.C2473F (on ENST00000389232; = p.C2474F on NM_001036.6) | Missense Mutation (SNP) | VAF 20/196 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SAMD7 | c.497T>C p.L166P | Missense Mutation (SNP) | VAF 19/182 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- SAMD8 | c.665A>T p.H222L | Missense Mutation (SNP) | VAF 25/222 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SBK3 | c.1021G>C p.D341H | Missense Mutation (SNP) | VAF 6/158 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.219); called by muse, mutect2
- SBSN | c.1595A>C p.N532T (on ENST00000452271 / NM_001166034.2; = p.N189T on NM_198538.4) | Missense Mutation (SNP) | VAF 42/150 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.027); called by mutect2, varscan2
- SFSWAP | c.923A>G p.N308S | Missense Mutation (SNP) | VAF 37/356 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SHLD1 | c.104G>A p.S35N | Missense Mutation (SNP) | VAF 40/331 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- SHOX2 | c.466G>T p.E156* (on ENST00000441443 / NM_006884.3; = p.E180* on NM_003030.4) | Nonsense Mutation (SNP) | VAF 92/470 reads (20%) | called by muse, mutect2, varscan2
- SIRPB1 | c.238A>T p.N80Y | Missense Mutation (SNP) | VAF 123/853 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- SLBP | c.129A>C p.E43D | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- SLC30A6 | c.594G>A p.M198I | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.042); called by muse, mutect2
- SLC38A3 | c.1511A>G p.H504R | Missense Mutation (SNP) | VAF 25/266 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC9A9 | c.136T>C p.F46L | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- SPACA7 | c.577G>C p.G193R | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- SPECC1 | c.581A>T p.Y194F | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPTBN5 | c.2395G>A p.A799T | Missense Mutation (SNP) | VAF 113/464 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SYTL5 | c.685G>T p.D229Y | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.44); called by muse, mutect2, varscan2
- TDRD5 | c.368A>C p.Y123S | Missense Mutation (SNP) | VAF 63/221 reads (29%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- TENM4 | c.4735T>C p.S1579P | Missense Mutation (SNP) | VAF 39/248 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- TOGARAM1 | c.3704C>T p.P1235L | Missense Mutation (SNP) | VAF 35/157 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TOR1AIP2 | c.202G>T p.D68Y | Missense Mutation (SNP) | VAF 86/253 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- TRAV23DV6 | c.162G>C p.E54D | Missense Mutation (SNP) | VAF 72/340 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TRBV7-1 | c.304C>A p.Q102K | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TRHDE | c.2494C>A p.Q832K | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- TTN | c.20152G>T p.V6718F (on ENST00000591111; = p.V5791F on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/64 reads (25%) | PolyPhen benign (0.32); called by muse, mutect2, varscan2
- UMAD1 | c.103A>G p.R35G | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZBED6 | c.2389G>A p.E797K | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- ZBED6 | c.2762A>T p.K921I | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2
- ZFHX4 | c.319G>T p.V107F | Missense Mutation (SNP) | VAF 32/295 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- ZFHX4 | c.2018C>G p.S673C | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- ZMAT2 | c.137G>T p.R46L | Missense Mutation (SNP) | VAF 37/159 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.687); called by muse, mutect2, varscan2
- ZNF394 | c.20C>A p.A7D | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.077); called by muse, mutect2
- ZNF445 | c.1286A>C p.D429A | Missense Mutation (SNP) | VAF 34/456 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.073); called by muse, mutect2
- ZNF804B | c.2093G>C p.R698T | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- ZSCAN5A | c.1417T>A p.C473S | Missense Mutation (SNP) | VAF 24/166 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ACP1 | c.93A>T p.V31= | Silent (SNP) | VAF 9/202 reads (4%) | called by muse, mutect2
- ADAMTS16 | c.2826G>T p.T942= | Silent (SNP) | VAF 18/116 reads (16%) | called by muse, varscan2
- ARHGEF28 | c.1983T>A p.S661= | Silent (SNP) | VAF 12/90 reads (13%) | called by muse, mutect2, varscan2
- BBS10 | c.291T>C p.L97= | Silent (SNP) | VAF 13/114 reads (11%) | called by muse, mutect2, varscan2
- BSN | c.11250G>C p.R3750= | Silent (SNP) | VAF 12/310 reads (4%) | catalogued as COSV56523414; called by muse, mutect2
- BTG1 | c.165C>T p.H55= | Silent (SNP) | VAF 24/354 reads (7%) | catalogued as rs756555997; called by muse, mutect2
- C1orf68 | c.396C>T p.C132= | Silent (SNP) | VAF 32/424 reads (8%) | catalogued as rs756929875; called by muse, mutect2
- C6 | c.1347T>C p.S449= | Silent (SNP) | VAF 16/184 reads (9%) | catalogued as rs1213000326; called by muse, mutect2
- CABP5 | c.378C>G p.T126= | Silent (SNP) | VAF 15/88 reads (17%) | catalogued as COSV99506625; called by muse, mutect2
- CAPN10 | c.1020G>T p.R340= | Silent (SNP) | VAF 49/188 reads (26%) | called by muse, mutect2, varscan2
- CCDC168 | c.9498T>C p.N3166= | Silent (SNP) | VAF 11/101 reads (11%) | called by muse, mutect2, varscan2
- CDH9 | c.1665C>A p.G555= | Silent (SNP) | VAF 35/166 reads (21%) | called by muse, mutect2, varscan2
- CFAP65 | c.879G>T p.G293= | Silent (SNP) | VAF 69/268 reads (26%) | catalogued as COSV55389390; called by muse, mutect2, varscan2
- COL22A1 | c.444G>T p.L148= | Silent (SNP) | VAF 20/170 reads (12%) | catalogued as COSV57362462; called by muse, mutect2, varscan2
- CR1 | c.3540C>T p.C1180= | Silent (SNP) | VAF 16/598 reads (3%) | called by muse, mutect2
- CYBB | c.180G>C p.L60= | Silent (SNP) | VAF 12/312 reads (4%) | catalogued as COSV66084864; called by muse, mutect2
- CYP2C19 | c.84A>G p.K28= | Silent (SNP) | VAF 22/182 reads (12%) | called by muse, mutect2, varscan2
- DCDC2B | c.1038T>A p.A346= | Silent (SNP) | VAF 63/259 reads (24%) | called by muse, mutect2, varscan2
- DGCR2 | c.144C>T p.P48= | Silent (SNP) | VAF 11/154 reads (7%) | called by muse, mutect2
- DNAH14 | c.9957G>C p.G3319= (on ENST00000445597; = p.G4327= on NM_001367479.1) | Silent (SNP) | VAF 18/183 reads (10%) | called by muse, mutect2, varscan2
- DOCK9 | c.3678G>T p.L1226= (on ENST00000376460 / NM_001366676.2; = p.L1227= on NM_015296.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 27/191 reads (14%) | called by muse, mutect2, varscan2
- FAM186A | c.5082T>C p.D1694= | Silent (SNP) | VAF 43/175 reads (25%) | called by muse, mutect2, varscan2
- FAT4 | c.7725G>T p.T2575= | Silent (SNP) | VAF 22/228 reads (10%) | catalogued as rs140288688; called by muse, mutect2
- FRAS1 | c.3415C>T p.L1139= | Silent (SNP) | VAF 34/231 reads (15%) | called by muse, mutect2, varscan2
- GABPB2 | c.237A>G p.A79= | Silent (SNP) | VAF 50/166 reads (30%) | called by muse, mutect2, varscan2
- GNAZ | c.975C>G p.T325= | Silent (SNP) | VAF 42/424 reads (10%) | catalogued as rs891790725; called by muse, mutect2
- HMCN2 | c.10362C>A p.P3454= | Silent (SNP) | VAF 75/274 reads (27%) | called by muse, mutect2, varscan2
- IMPDH1 | c.162C>T p.A54= (on ENST00000470772 / NM_001142573.2; = p.A139= on NM_000883.4) | Silent (SNP) | VAF 18/534 reads (3%) | called by muse, mutect2
- INPP5J | c.2217A>T p.P739= (on ENST00000331075 / NM_001284285.2; = p.P371= on NM_001002837.2) | Silent (SNP) | VAF 42/363 reads (12%) | called by muse, mutect2, varscan2
- KCNG1 | c.1347C>A p.I449= | Silent (SNP) | VAF 38/207 reads (18%) | called by muse, mutect2, varscan2
- KIF13A | c.3681A>T p.T1227= | Silent (SNP) | VAF 33/96 reads (34%) | catalogued as COSV52454745; called by muse, mutect2, varscan2
- LAMB3 | c.1821C>T p.A607= | Silent (SNP) | VAF 26/470 reads (6%) | catalogued as rs751762651; called by muse, mutect2
- LKAAEAR1 | c.273C>G p.P91= | Silent (SNP) | VAF 47/204 reads (23%) | catalogued as COSV57478909; called by muse, mutect2, varscan2
- LOXL2 | c.195G>A p.R65= | Silent (SNP) | VAF 66/268 reads (25%) | called by muse, mutect2, varscan2
- LPXN | c.357A>G p.P119= | Silent (SNP) | VAF 24/137 reads (18%) | called by muse, mutect2, varscan2
- LRRTM1 | c.1290G>T p.T430= | Silent (SNP) | VAF 21/246 reads (9%) | catalogued as COSV99702338; called by muse, mutect2
- MAGEA1 | c.54C>T p.A18= | Silent (SNP) | VAF 24/85 reads (28%) | called by muse, mutect2, varscan2
- MAGEL2 | c.3186C>T p.I1062= | Silent (SNP) | VAF 22/195 reads (11%) | called by muse, mutect2, varscan2
- MMP26 | c.360G>C p.V120= | Silent (SNP) | VAF 6/111 reads (5%) | catalogued as COSV56174147; called by muse, mutect2
- MUC16 | c.41682C>A p.P13894= | Silent (SNP) | VAF 32/144 reads (22%) | called by muse, mutect2, varscan2
- MYBPC2 | c.750C>A p.V250= | Silent (SNP) | VAF 14/70 reads (20%) | called by muse, mutect2, varscan2
- MYPOP | c.153G>A p.E51= | Silent (SNP) | VAF 87/321 reads (27%) | catalogued as rs750839806; called by muse, mutect2, varscan2
- NAGPA | c.111A>G p.L37= | Silent (SNP) | VAF 32/174 reads (18%) | called by muse, varscan2
- NDUFC1 | c.105G>T p.P35= | Silent (SNP) | VAF 47/256 reads (18%) | called by muse, mutect2, varscan2
- NUAK1 | c.387G>A p.V129= | Silent (SNP) | VAF 11/92 reads (12%) | called by muse, mutect2, varscan2
- OR2M4 | c.603T>A p.I201= | Silent (SNP) | VAF 87/273 reads (32%) | called by muse, mutect2, varscan2
- OR2V2 | c.738G>T p.L246= | Silent (SNP) | VAF 42/188 reads (22%) | called by muse, mutect2, varscan2
- OR4M1 | c.75A>T p.L25= | Silent (SNP) | VAF 15/254 reads (6%) | called by muse, mutect2
- OR51D1 | c.315C>A p.I105= | Silent (SNP) | VAF 26/259 reads (10%) | catalogued as COSV100712435; called by muse, mutect2
- OR8B4 | c.591A>G p.V197= | Silent (SNP) | VAF 44/277 reads (16%) | catalogued as COSV100635776; called by muse, mutect2, varscan2
- OTUB2 | c.648T>A p.V216= | Silent (SNP) | VAF 52/456 reads (11%) | called by muse, mutect2, varscan2
- PAPOLA | c.897A>T p.V299= | Silent (SNP) | VAF 104/281 reads (37%) | called by muse, mutect2, varscan2
- PEX19 | c.42G>A p.A14= | Silent (SNP) | VAF 152/535 reads (28%) | catalogued as rs1357331804; called by muse, mutect2, varscan2
- PPP1R35 | c.153C>T p.D51= | Silent (SNP) | VAF 5/13 reads (38%) | called by muse, mutect2, varscan2
- PRR5L | c.285C>T p.D95= | Silent (SNP) | VAF 15/187 reads (8%) | catalogued as COSV61123191; called by muse, mutect2
- PTGES2 | c.828C>T p.A276= | Silent (SNP) | VAF 74/296 reads (25%) | catalogued as rs763899980; called by muse, mutect2, varscan2
- PTPN13 | c.5946G>A p.K1982= (on ENST00000411767 / NM_080683.3; = p.K1963= on NM_006264.3) | Silent (SNP) | VAF 40/284 reads (14%) | catalogued as rs764597117; called by muse, mutect2, varscan2
- RBFOX2 | c.45C>G p.P15= | Silent (SNP) | VAF 9/110 reads (8%) | called by muse, mutect2
- RC3H2 | c.2394T>G p.P798= | Silent (SNP) | VAF 33/177 reads (19%) | called by muse, mutect2, varscan2
- REG4 | c.15C>T p.S5= | Silent (SNP) | VAF 52/223 reads (23%) | called by muse, mutect2, varscan2
- RESP18 | c.474G>T p.L158= | Silent (SNP) | VAF 25/293 reads (9%) | catalogued as COSV61114211; called by muse, mutect2
- RGPD4 | c.2217C>A p.P739= | Silent (SNP) | VAF 58/336 reads (17%) | called by muse, mutect2, varscan2
- RRP8 | c.927C>T p.S309= | Silent (SNP) | VAF 23/186 reads (12%) | catalogued as COSV54449016; called by muse, mutect2, varscan2
- RYR1 | c.3868C>T p.L1290= | Silent (SNP) | VAF 87/428 reads (20%) | catalogued as rs745572367; called by muse, mutect2, varscan2
- SCART1 | c.2412G>T p.A804= | Silent (SNP) | VAF 14/113 reads (12%) | called by muse, mutect2, varscan2
- SCN3A | c.1200C>T p.Y400= | Silent (SNP) | VAF 23/333 reads (7%) | called by muse, mutect2
- SLC22A9 | c.198C>A p.A66= | Silent (SNP) | VAF 36/154 reads (23%) | catalogued as COSV54170677; called by muse, mutect2, varscan2
- SLC46A2 | c.264C>G p.S88= | Silent (SNP) | VAF 8/216 reads (4%) | called by muse, mutect2
- SLIT3 | c.4362C>A p.V1454= | Silent (SNP) | VAF 31/189 reads (16%) | catalogued as COSV60632637; called by muse, mutect2, varscan2
- SOCS6 | c.1242C>T p.D414= | Silent (SNP) | VAF 13/104 reads (13%) | catalogued as rs757419081; called by muse, mutect2, varscan2
- SPATA31D4 | c.2391C>T p.N797= | Silent (SNP) | VAF 69/543 reads (13%) | catalogued as rs779794288; called by muse, mutect2, varscan2
- SREBF2 | c.1722C>T p.F574= | Silent (SNP) | VAF 56/472 reads (12%) | called by muse, mutect2, varscan2
- ST8SIA5 | c.726G>T p.A242= | Silent (SNP) | VAF 38/201 reads (19%) | catalogued as COSV59333177; called by muse, mutect2, varscan2
- SUCLA2 | c.1122A>C p.T374= (on ENST00000643023; = p.T353= on NM_003850.3) | Silent (SNP) | VAF 42/292 reads (14%) | called by muse, mutect2, varscan2
- TARM1 | c.87G>A p.R29= (on ENST00000616041 / NM_001330650.1; = p.R21= on NM_001135686.3) | Silent (SNP) | VAF 57/295 reads (19%) | catalogued as COSV71524954; called by muse, mutect2, varscan2
- TGFBR3L | c.645C>A p.A215= | Silent (SNP) | VAF 43/193 reads (22%) | called by muse, mutect2, varscan2
- TPO | c.897G>T p.G299= | Silent (SNP) | VAF 83/311 reads (27%) | called by muse, mutect2, varscan2
- TRANK1 | c.2892T>C p.H964= | Silent (SNP) | VAF 31/220 reads (14%) | called by muse, mutect2, varscan2
- TTN | c.6693C>G p.L2231= (on ENST00000591111; = p.L2185= on NM_003319.4) | Silent (SNP) | VAF 12/164 reads (7%) | called by muse, mutect2
- UNC79 | c.1023C>G p.L341= (on ENST00000393151 / NM_001346218.2; = p.L164= on NM_020818.5) | Silent (SNP) | VAF 21/393 reads (5%) | catalogued as COSV56403517, COSV99828067; called by muse, mutect2
- URM1 | c.72A>G p.K24= | Silent (SNP) | VAF 34/160 reads (21%) | called by muse, mutect2, varscan2
- XIRP1 | c.946C>T p.L316= | Silent (SNP) | VAF 7/68 reads (10%) | called by muse, mutect2, varscan2
- ZNF23 | c.1077A>T p.T359= | Silent (SNP) | VAF 55/283 reads (19%) | called by muse, mutect2, varscan2
- ZNF527 | c.396T>C p.Y132= | Silent (SNP) | VAF 58/348 reads (17%) | catalogued as rs753911605; called by muse, mutect2, varscan2
- ZNF749 | c.1263C>G p.L421= | Silent (SNP) | VAF 23/145 reads (16%) | called by muse, mutect2, varscan2
- ABCB1 | c.1351-9T>C | Intron (SNP) | VAF 41/456 reads (9%) | catalogued as rs368991349; called by muse, mutect2
- AC005400.1 | n.87-20799C>T | Intron (SNP) | VAF 48/306 reads (16%) | catalogued as rs551006708; called by muse, mutect2, varscan2
- AC073310.1 | n.218T>A | RNA (SNP) | VAF 30/208 reads (14%) | called by muse, mutect2, varscan2
- AC107023.1 | n.25+5495C>A | Intron (SNP) | VAF 30/148 reads (20%) | called by muse, mutect2
- AKR1B1 | c.67-46G>T | Intron (SNP) | VAF 27/294 reads (9%) | called by muse, mutect2
- AL353804.4 | chrX:73822153 A>C | 5'Flank (SNP) | VAF 12/157 reads (8%) | called by muse, mutect2
- BOD1P2 | n.73C>A | RNA (SNP) | VAF 16/44 reads (36%) | called by muse, mutect2
- BRAF | chr7:140924741 G>C | 5'Flank (SNP) | VAF 22/204 reads (11%) | called by muse, mutect2
- BRD3 | c.1644-214C>T | Intron (SNP) | VAF 24/179 reads (13%) | catalogued as rs762778847; called by muse, mutect2, varscan2
- CCER1 | c.*1A>T | 3'UTR (SNP) | VAF 10/60 reads (17%) | catalogued as rs757860865; called by muse, mutect2, varscan2
- CDH23 | c.-72G>T | 5'UTR (SNP) | VAF 6/31 reads (19%) | called by muse, mutect2, varscan2
- CELF6 | chr15:72320215 C>A | 5'Flank (SNP) | VAF 21/86 reads (24%) | called by muse, varscan2
- CES1P1 | n.478G>A | RNA (SNP) | VAF 133/586 reads (23%) | called by muse, mutect2, varscan2
- COL5A1 | c.2332-14C>A | Intron (SNP) | VAF 20/347 reads (6%) | called by muse, mutect2
- CR1L | c.*13A>T | 3'UTR (SNP) | VAF 7/104 reads (7%) | catalogued as rs1402087501; called by muse, mutect2
- DCHS2 | n.1433A>T | RNA (SNP) | VAF 54/346 reads (16%) | called by muse, mutect2, varscan2
- DEPDC5 | c.3186-32T>A | Intron (SNP) | VAF 23/208 reads (11%) | called by muse, mutect2, varscan2
- GRIA4 | c.2295-5926G>A | Intron (SNP) | VAF 14/260 reads (5%) | called by muse, mutect2
- ITK | c.985+13G>C | Intron (SNP) | VAF 46/270 reads (17%) | called by muse, mutect2, varscan2
- KHDC3L | c.*37G>C | 3'UTR (SNP) | VAF 81/229 reads (35%) | called by muse, mutect2, varscan2
- LINC02740 | n.103G>A | RNA (SNP) | VAF 9/172 reads (5%) | catalogued as rs1564973222; called by muse, mutect2
- LTBP1 | c.1034-299T>A | Intron (SNP) | VAF 26/260 reads (10%) | called by muse, mutect2
- MED23 | c.159+19A>G | Intron (SNP) | VAF 57/256 reads (22%) | catalogued as rs746808551; called by muse, mutect2, varscan2
- MKS1 | c.749+19G>A | Intron (SNP) | VAF 91/408 reads (22%) | catalogued as COSV58302541; called by muse, mutect2, varscan2
- MXRA8 | chr1:1361293 T>C | 5'Flank (SNP) | VAF 17/138 reads (12%) | called by muse, mutect2, varscan2
- NECTIN3 | c.160+286dup | Intron (INS) | VAF 23/171 reads (13%) | called by mutect2, pindel, varscan2
- NIBAN3 | c.1843+45G>T | Intron (SNP) | VAF 43/151 reads (28%) | called by muse, mutect2, varscan2
- NOC2LP2 | n.791G>T | RNA (SNP) | VAF 85/333 reads (26%) | called by muse, mutect2, varscan2
- NPIPP1 | n.405del | RNA (DEL) | VAF 119/788 reads (15%) | catalogued as COSV100440102; called by mutect2, pindel, varscan2
- NRXN2 | c.3403+5504C>T | Intron (SNP) | VAF 19/104 reads (18%) | catalogued as rs1224078570; called by muse, mutect2, varscan2
- PLCZ1 | c.-91G>T | 5'UTR (SNP) | VAF 32/259 reads (12%) | catalogued as COSV99856073; called by muse, mutect2, varscan2
- PSG6 | c.706+20C>G | Intron (SNP) | VAF 62/254 reads (24%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159336 T>A | 5'Flank (SNP) | VAF 24/108 reads (22%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159906 C>A | 5'Flank (SNP) | VAF 26/79 reads (33%) | catalogued as rs8048216; called by muse, mutect2, varscan2
- RNY4P30 | chr13:49892344 A>T | 5'Flank (SNP) | VAF 61/312 reads (20%) | called by muse, mutect2, varscan2
- SERPINA4 | c.-18+137C>T | Intron (SNP) | VAF 66/559 reads (12%) | called by muse, mutect2, varscan2
- SKAP1 | c.978+5975A>G | Intron (SNP) | VAF 11/173 reads (6%) | catalogued as rs1338531929; called by muse, mutect2
- SNORD109A | chr15:25041962 G>T | 5'Flank (SNP) | VAF 16/110 reads (15%) | called by muse, mutect2, varscan2
- SNORD114-29 | n.42G>T | RNA (SNP) | VAF 31/182 reads (17%) | called by muse, mutect2, varscan2
- SRP19 | c.*524C>A | 3'UTR (SNP) | VAF 57/376 reads (15%) | called by muse, mutect2, varscan2
- SSU72 | chr1:1575201 T>A | 5'Flank (SNP) | VAF 103/330 reads (31%) | called by muse, mutect2, varscan2
- TP63 | c.325-18531del | Intron (DEL) | VAF 8/51 reads (16%) | catalogued as rs1263671418, COSV53217690; called by mutect2, pindel, varscan2
- TPT1 | c.-19T>C | 5'UTR (SNP) | VAF 61/261 reads (23%) | called by muse, mutect2, varscan2
- UNC93B1 | c.97-33A>T | Intron (SNP) | VAF 23/119 reads (19%) | called by muse, mutect2
- VAPB | c.-31C>A | 5'UTR (SNP) | VAF 81/389 reads (21%) | called by muse, mutect2, varscan2
- VAPB | c.396+26A>G | Intron (SNP) | VAF 29/157 reads (18%) | called by muse, mutect2, varscan2
- WDR86 | chr7:151411715 C>T | 5'Flank (SNP) | VAF 17/152 reads (11%) | catalogued as rs981625508; called by muse, mutect2
- XIAP | c.*958A>G | 3'UTR (SNP) | VAF 46/163 reads (28%) | called by muse, mutect2, varscan2
- ZNF398 | c.-24G>C | 5'UTR (SNP) | VAF 16/61 reads (26%) | called by muse, mutect2, varscan2
